Gene-level copy-number profile of tumor specimen C3N-02789-01 from CPTAC case C3N-02789, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 61.9 years (22,610 days).
Specimen C3N-02789-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4950dccd-afdd-4566-9906-a1c458884f1e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02789-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second AscatNGS file.
https://portal.gdc.cancer.gov/files/10619b30-8abb-43d9-bbc9-69ff6b082a48

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 2: 26; copy number 4: 55,693; copy number 5: 138; copy number 6: 2,525; copy number 9: 5.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:84,999,812–85,849,199, 14 genes: PPIAP79, AC114928.1, RBBP4P6, AC117522.3, AC117522.2, AC117522.1, AC010486.1, AC010486.2, AC010486.3, RPL5P17, AC026700.1, AC010595.1, RPS2P25, AC026414.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes, copy number 9: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr22:18,715,815–18,719,341, 1 gene, copy number 9: PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
